Somatic mutation profile of tumor specimen MBCProject_0960_T3_WES (aliquot MBCProject_0960_T3_WES_1) from CMI case MBCProject_0960, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 34.8 years (12,724 days).
Specimen MBCProject_0960_T3_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9eb221b1-141f-45f4-83b0-221f02b13553.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0960_SALIVA (Saliva), aliquot MBCProject_0960_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2803c237-5618-4d56-ab96-a7ecf2b5e642

The open-access MAF lists 56 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, Intron 4, Nonsense Mutation 3, 3'Flank 2, 5'Flank 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAP3 | c.2416C>G p.P806A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs774777723; called by mutect2, varscan2
- AREL1 | c.1682A>G p.K561R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774314378; called by muse, mutect2, varscan2
- ERP44 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV99316465; called by muse, mutect2, varscan2
- GYPA | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV51619504; called by muse, mutect2, varscan2
- KCNG2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777174838; called by muse, mutect2, varscan2
- MAP4K2 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs762109609, COSV99581664; called by muse, mutect2, varscan2
- OR5H15 | c.83T>C p.F28S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs773196019; called by muse, mutect2, varscan2
- PDCD11 | c.5239G>T p.V1747L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV53298127; called by muse, mutect2, varscan2
- PTEN | c.812T>C p.F271S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs142420551, COSV64289376; called by muse, mutect2, varscan2
- SLC15A5 | c.565dup p.T189Nfs*6 | Frame Shift Ins (INS) | VAF 8/58 reads (14%) | catalogued as rs759187780; called by mutect2, pindel, varscan2
- TBC1D12 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs1378102625, COSV56552945; called by muse, mutect2, varscan2
- TNC | c.1495C>A p.R499S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV60783280; called by muse, mutect2, varscan2
- TTC17 | c.620G>A p.S207N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs746632563; called by muse, mutect2, varscan2
- USP40 | c.704T>A p.L235* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99297064; called by muse, mutect2, varscan2
- ACLY | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); called by muse, varscan2
- ACLY | c.59G>C p.C20S | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.945); called by muse, varscan2
- ANKRD30A | c.2023T>A p.S675T (on ENST00000611781; = p.S619T on NM_052997.2) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- ATP6V1B2 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); called by muse, varscan2
- CAMSAP1 | c.2000C>A p.T667K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CPD | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DCUN1D5 | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAT2 | c.6949G>A p.D2317N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.029); called by mutect2, varscan2
- GATA3 | c.1219_1220del p.S407Afs*99 | Frame Shift Del (DEL) | VAF 38/170 reads (22%) | called by pindel, varscan2
- HSF1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- IFTAP | c.572A>C p.K191T | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRT25 | c.957G>A p.T319= | Splice Region (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- LHX4 | c.457T>A p.S153T | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.09); called by muse, mutect2
- LRP3 | c.932A>G p.Y311C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYH13 | c.1800G>T p.K600N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- NLRC3 | c.1426T>G p.F476V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR56B1 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PCED1A | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF146 | c.530G>A p.G177E (on ENST00000368314 / NM_001242850.2; = p.G176E on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTL9 | c.2506C>A p.Q836K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SLC4A9 | c.2549C>A p.A850E (on ENST00000507527 / NM_001258428.2; = p.A826E on NM_031467.3) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- SYT10 | c.596G>C p.R199P | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TCF4 | c.526G>C p.V176L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- TSHZ2 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- YJU2 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ZFHX3 | c.7363C>T p.Q2455* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | called by mutect2, varscan2
- ARFRP1 | c.426C>T p.L142= | Silent (SNP) | VAF 36/229 reads (16%) | called by muse, mutect2, varscan2
- KATNIP | c.3465T>C p.D1155= | Silent (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- KIF26B | c.5193G>A p.K1731= | Silent (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- MEGF11 | c.1269T>C p.T423= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- OR10J3 | c.259T>C p.L87= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as rs1480580849; called by muse, mutect2, varscan2
- OSCP1 | c.645C>T p.L215= (on ENST00000356637 / NM_001330493.1; = p.L205= on NM_145047.5) | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV99347266; called by muse, mutect2, varscan2
- RANBP17 | c.1398A>G p.Q466= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- SNPH | c.1117C>T p.L373= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- VWA5B1 | c.1374G>A p.R458= | Silent (SNP) | VAF 77/291 reads (26%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851580 C>G | 3'Flank (SNP) | VAF 23/321 reads (7%) | called by muse, mutect2
- HIF1A | c.35+2090T>A | Intron (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2
- IGFBP3 | chr7:45921674 G>A | 5'Flank (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- MYO3A | c.731+37C>T | Intron (SNP) | VAF 20/78 reads (26%) | catalogued as rs370268854; called by muse, mutect2, varscan2
- NOTCH4 | c.5298+34_5298+37del | Intron (DEL) | VAF 22/96 reads (23%) | catalogued as rs775859701; called by mutect2, pindel, varscan2
- RPL10 | c.492+20C>T | Intron (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- ZNF614 | chr19:52013176 G>A | 3'Flank (SNP) | VAF 8/35 reads (23%) | catalogued as rs1264644089; called by muse, mutect2, varscan2
